Surgical pathology report (de-identified scan), TCGA case TCGA-G9-7523, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-7523-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

SPECIMEN(S):

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

DIAGNOSIS:

- A. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 5+5 (10/10), INVOLVING APPROXIMATELY 35% OF THE EXAMINED PROSTATIC TISSUE
- TUMOR INVOLVES APEX; LEVEL I LEFT AND RIGHT ANTERIOR; LEVEL II LEFT LATERAL AND ANTERIOR; LEVEL III LEFT AND RIGHT ANTERIOR; LEVEL III RIGHT POSTERIOR; LEFT AND RIGHT MID BASE
- EXTRAPROSTATIC EXTENSIONS ARE PRESENT AT ANTERIOR AND MID BASE
- SURGICAL MARGINS AT APEX, ANTERIOR AND BASE ARE POSITIVE FOR CARCINOMA (LINEAR DISTANCE APPROXIMATELY 8MM IN AGGREGATE)
- PERINEURAL INVASION IDENTIFIED
- NO LYMPHOVASCULAR INVASION IDENTIFIED
- SEMINAL VESICLES/VAS DEFERENS ARE UNINVOLVED BY TUMOR
- SEE SYNOPTIC REPORT
- SEE COMMENT
- B. LYMPH NODES, RIGHT PELVIC, EXCISION:
- FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4)
- C. LYMPH NODES, LEFT PELVIC, EXCISION:
- SIX LYMPH NODES, NEGATIVE FOR CARCINOMA (0/6)

Comment: reviewed slides A3, A4, A6, A9-A12, A14, A16, A23, and A24.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE
B: RIGHT PELVIC LYMPH NODES
C: LEFT PELVIC LYMPH NODES

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 35%

Gleason Grade/Sum:: Grade 5 + 5 , Sum 10

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: anterior, mid base

Bladder Neck Involved: No

Margins Involvement: Yes

Location: apex, anterior, mid base

Linear Distance: Focal (1-10mm)

Frozen Performed: No

[page 2 of 3]
[REDACTED]

Lymph Nodes: Negative Right 0 / 4 Left 0 / 6
Other Pathologic Findings: focal chronic inflammation
Pathological Staging (pTNM): p T 3a N 0 M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition
pT3a: Extraprostatic extension or microscopic invasion of bladder neck.

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and "prostate" is a 36 g resected prostate gland measuring 4.2 cm from right lateral to left lateral, 3.2 cm from anterior to posterior, and 2.3 cm from apex to base. The capsule is smooth, red, and intact. Ink code: anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, and posterior-black. After removal of apex and base, the prostate weighs 16 g and has a nodular tan parenchyma. The right seminal vesicle is 3.7 x 2.1 x 0.9 cm and the left is 3.7 x 2 x 0.9 cm; they consist of cystic tan tissue. The right vas deferens is 3 x 0.8 cm and the left is 2.3 x 0.7 cm; they consist of tubular tan tissue. Tissue is procured (7 g); submitted entirely:

A1-A3: perpendicular sections of apex

A4: level 1, right anterior

A5: level 1, right posterior

A6: level 1, left anterior

A7: level 1, left posterior

A8: level 2, right lateral and posterior capsule

A9: level 2, left lateral and anterior capsule

A10: level 3, right anterior

A11: level 3, right posterior

A12: level 3, left anterior

A13: level 3, left posterior

A14-A15: perpendicular sections of right mid base

A16: perpendicular section of left mid base

A17-A18: perpendicular section of right lateral base

A19-A20: perpendicular section of left lateral base

A21: perpendicular section of right posterior base

A22: perpendicular section of left posterior base

A23: perpendicular section of right mid base urethral orifice margin

A24: perpendicular section of left mid base urethral orifice margin

A25: right seminal vesicle and vas deferens

A26: left seminal vesicle and vas deferens

B. RIGHT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and "right pelvic lymph node" are pieces of yellow-tan soft tissue in aggregate, 4.2 x 2.5 x 0.7 cm containing 3 possible lymph nodes, 1.1 x 0.7 x 0.4 cm, 1.8 x 0.9 x 0.4 cm, and 3.3 x 1.4 x 0.7 cm. Larger lymph node is bisected and has a variegated red-tan cut surface; submitted entirely:

B1: 2 possible lymph nodes

B2-B3: 1 bisected lymph node

B4: remainder of soft tissue

C. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and "left pelvic lymph node" are pieces of yellow-tan soft tissue in aggregate, 3.9 x 2.3 x 1 cm containing possible lymph nodes ranging from 0.2 x 0.2 x 0.2 cm to 3.1 x 1.9 x 0.6 cm. The larger lymph nodes are bisected and have pink-tan cut surfaces; submitted entirely:

C1: 3 possible lymph nodes

C2: 1 bisected lymph node

C3-C4: 1 bisected lymph node

C5: remainder of soft tissue

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Microscopic/Diagnostic Dictation: Pathologist, [REDACTED]

Final Review: Pathologist, [REDACTED]

[page 3 of 3]
[REDACTED]

FinalPathologist, [REDACTED]

Source: NCI Genomic Data Commons file 9e8568c6-a5a9-4486-954d-61e9bb6a4e54 (TCGA-G9-7523.8A16D779-BCF3-4371-87EC-3CD68330B1D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).